TARGET case TARGET-30-PAILZJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/74ad8c69-a0fa-5f1a-b577-b36c1a6d8680

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 3.5 years (1,261 days); Year of diagnosis: 1997; Days to last follow up: 765 days (2.1 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAILZJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
